Somatic mutation profile of tumor specimen C3L-02382-03 (aliquot CPT0190700011) from CPTAC case C3L-02382, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G2; Age at diagnosis: 63.8 years (23,312 days).
Specimen C3L-02382-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 129ec865-e1f5-4c2b-adf2-0b8d6ef1ec8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02382-32 (Blood Derived Normal), aliquot CPT0191130002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbc1d24e-e2db-4914-a701-4d7cc880b955

The open-access MAF lists 728 somatic variants for this specimen: 489 protein-altering or splice-affecting, 144 silent, 95 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 321, Silent 144, Frame Shift Del 99, Intron 46, Frame Shift Ins 27, Nonsense Mutation 21, 3'UTR 16, RNA 13, Splice Site 12, 5'UTR 7, 3'Flank 7, 5'Flank 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5012del p.N1671Ifs*4 (on ENST00000272895 / NM_173076.3; = p.N1353Ifs*4 on NM_015657.3) | Frame Shift Del (DEL) | VAF 98/351 reads (28%) | catalogued as rs387906285, CD051281; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ANKRD11 | c.6982dup p.R2328Pfs*204 | Frame Shift Ins (INS) | VAF 42/253 reads (17%) | catalogued as rs1555525088; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- B4GALNT1 | c.263del p.G88Afs*24 | Frame Shift Del (DEL) | VAF 42/302 reads (14%) | catalogued as rs745744124; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KIF21A | c.2860C>T p.R954W (on ENST00000361418 / NM_001378440.1; = p.R941W on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/308 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs121912585, CM033625, COSV100735326; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 119/360 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NKX6-2 | c.234del p.L79Cfs*109 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | catalogued as rs765650727; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- PPP2R1A | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as rs1555791268, COSV59042459, COSV59042650; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- PTEN | c.406T>C p.C136R | Missense Mutation (SNP) | VAF 146/486 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs786201044, CM004336, COSV100911109, COSV64289087; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.548del p.K183Rfs*16 | Frame Shift Del (DEL) | VAF 62/261 reads (24%) | catalogued as rs1554900593, COSV64301859; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ADAMTS17 | c.1721del p.P575Lfs*13 | Frame Shift Del (DEL) | VAF 104/321 reads (32%) | catalogued as rs779966272; called by mutect2, pindel, varscan2
- ADGRL2 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs577293051, COSV54692230; called by muse, mutect2, varscan2
- ANK1 | c.3298G>A p.V1100I | Missense Mutation (SNP) | VAF 25/326 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs147741842; called by muse, mutect2
- ANK3 | c.7922C>T p.A2641V | Missense Mutation (SNP) | VAF 123/473 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV55083424; called by muse, mutect2, varscan2
- ARHGAP45 | c.842del p.G281Afs*16 | Frame Shift Del (DEL) | VAF 42/187 reads (22%) | catalogued as COSV57429840; called by mutect2, varscan2
- ARHGEF40 | c.4249C>T p.R1417C | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as rs779892227; called by muse, mutect2, varscan2
- ARMC6 | c.608G>C p.R203P (on ENST00000392336; = p.R178P on NM_033415.4) | Missense Mutation (SNP) | VAF 172/533 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs373198003; called by muse, mutect2, varscan2
- ASTL | c.1168G>A p.G390R | Missense Mutation (SNP) | VAF 160/489 reads (33%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as rs757814790; called by muse, mutect2, varscan2
- ATAT1 | c.901C>T p.H301Y | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as rs1300189963; called by muse, mutect2
- BCL3 | c.220dup p.H74Pfs*51 | Frame Shift Ins (INS) | VAF 15/58 reads (26%) | catalogued as rs770262318; called by mutect2, varscan2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | catalogued as rs1455506786, COSV59000653; called by mutect2, pindel, varscan2
- BTAF1 | c.2317C>T p.R773* | Nonsense Mutation (SNP) | VAF 77/273 reads (28%) | catalogued as rs903404922; called by muse, mutect2, varscan2
- C19orf57 | c.1942del p.L648Cfs*25 (on ENST00000586783 / NM_001345843.1; = p.L617Cfs*25 on NM_024323.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 98/364 reads (27%) | catalogued as rs1270763461; called by mutect2, pindel, varscan2
- CACNA1C | c.1487G>A p.R496Q | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.309); catalogued as rs369255950, COSV100215966; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1G | c.6948dup p.E2317Rfs*34 | Frame Shift Ins (INS) | VAF 14/50 reads (28%) | catalogued as rs766047428; called by mutect2, varscan2
- CCNQ | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 26/446 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs782228548; called by muse, mutect2
- CCT6B | c.442C>T p.L148F | Missense Mutation (SNP) | VAF 43/233 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs764453241; called by muse, mutect2, varscan2
- CDH22 | c.904G>T p.E302* | Nonsense Mutation (SNP) | VAF 104/440 reads (24%) | catalogued as COSV64840020; called by muse, varscan2
- CDK5R2 | c.336del p.D113Tfs*92 | Frame Shift Del (DEL) | VAF 86/322 reads (27%) | catalogued as rs1559429647, COSV56937071; called by mutect2, pindel, varscan2
- CDNF | c.493dup p.T165Nfs*2 | Frame Shift Ins (INS) | VAF 62/283 reads (22%) | catalogued as rs1245164692; called by mutect2, pindel, varscan2
- CEP126 | c.2193del p.E732Kfs*25 | Frame Shift Del (DEL) | VAF 45/251 reads (18%) | catalogued as rs755857306; called by mutect2, pindel, varscan2
- CEP135 | c.2369G>A p.R790H | Missense Mutation (SNP) | VAF 88/290 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs149552948; called by muse, mutect2, varscan2
- CEP295 | c.1657del p.T553Lfs*15 | Frame Shift Del (DEL) | VAF 42/144 reads (29%) | catalogued as rs749718914; called by mutect2, varscan2
- CERS5 | c.773A>C p.K258T | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1171374333; called by muse, mutect2, varscan2
- CHD4 | c.2335C>T p.R779W (on ENST00000357008 / NM_001363606.2; = p.R792W on NM_001273.5) | Missense Mutation (SNP) | VAF 95/297 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58901404; called by muse, mutect2, varscan2
- CLIP4 | c.2056C>T p.R686* | Nonsense Mutation (SNP) | VAF 42/150 reads (28%) | catalogued as rs1388847657; called by muse, mutect2, varscan2
- CLUH | c.2116G>A p.G706S (on ENST00000435359; = p.G745S on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/330 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs745874735; called by muse, mutect2, varscan2
- COCH | c.35-4G>A | Splice Region (SNP) | VAF 166/594 reads (28%) | catalogued as rs776171634; called by muse, mutect2, varscan2
- COL19A1 | c.2375G>C p.G792A | Missense Mutation (SNP) | VAF 48/204 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59565730; called by muse, mutect2, varscan2
- CORO2B | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 26/508 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs192155851, COSV55952626; called by muse, mutect2
- CRYBG1 | c.620dup p.D208* | Frame Shift Ins (INS) | VAF 30/139 reads (22%) | catalogued as rs1018039182; called by mutect2, varscan2
- CSF2RB | c.1701del p.S568Afs*130 | Frame Shift Del (DEL) | VAF 104/388 reads (27%) | catalogued as rs757082963; called by mutect2, pindel, varscan2
- CSH2 | c.116C>A p.A39D | Missense Mutation (SNP) | VAF 176/1314 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV100400317, COSV61080007; called by muse, mutect2, varscan2
- CYP1B1 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs72549376, CM014344; called by muse, mutect2
- CYP2A6 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 76/227 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.046); catalogued as COSV56535068; called by muse, mutect2, varscan2
- DAAM2 | c.2455G>A p.G819R | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51321336; called by muse, mutect2, varscan2
- DCAF1 | c.2809dup p.Q937Pfs*20 | Frame Shift Ins (INS) | VAF 125/412 reads (30%) | catalogued as rs782606429; called by mutect2, varscan2
- DCC | c.3841C>T p.P1281S | Missense Mutation (SNP) | VAF 37/800 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.696); catalogued as rs186927711; called by muse, mutect2
- DCLK1 | c.2101C>T p.R701C (on ENST00000360631 / NM_001330072.2; = p.D725= on NM_004734.5) | Missense Mutation (SNP) | VAF 100/314 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV55189268; called by muse, mutect2, varscan2
- DEFB132 | c.127del p.E43Rfs*51 | Frame Shift Del (DEL) | VAF 88/506 reads (17%) | catalogued as rs776618282; called by mutect2, pindel, varscan2
- DNAH17 | c.12596C>T p.A4199V | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.127); catalogued as COSV53143267; called by muse, mutect2
- DOCK10 | c.1272del p.F424Lfs*2 | Frame Shift Del (DEL) | VAF 54/250 reads (22%) | catalogued as rs1559599687; called by mutect2, pindel
- DPH7 | c.718A>G p.M240V | Missense Mutation (SNP) | VAF 103/311 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs971597043; called by muse, mutect2, varscan2
- DUSP3 | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 26/300 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1321500053, COSV56825023; called by muse, mutect2
- DZIP3 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.197); catalogued as rs137935085; called by muse, varscan2
- EGLN2 | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 9/245 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1190794600, COSV58281200; called by muse, mutect2
- ELP4 | c.1126del p.R376Gfs*19 (on ENST00000350638; = p.R375Gfs*19 on NM_019040.5) | Frame Shift Del (DEL) | VAF 20/115 reads (17%) | catalogued as COSV100635815; called by mutect2, pindel, varscan2
- ETV5 | c.943G>A p.G315R | Missense Mutation (SNP) | VAF 111/391 reads (28%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.919); catalogued as rs766071992, COSV100112532; called by muse, mutect2, varscan2
- EVX2 | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 161/455 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV57962984; called by muse, mutect2, varscan2
- EXOC6B | c.1997C>T p.T666I | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV55571817; called by muse, mutect2
- FAAH2 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.336); catalogued as rs779489870, COSV100887436; called by muse, mutect2, varscan2
- FADS3 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 146/477 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53880847; called by muse, mutect2, varscan2
- FAM135B | c.1918C>T p.P640S | Missense Mutation (SNP) | VAF 69/188 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.02); catalogued as COSV99417615; called by muse, mutect2, varscan2
- FAM161A | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 147/546 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as rs780565318, COSV100281145; called by muse, mutect2, varscan2
- FAT2 | c.7238G>A p.R2413H | Missense Mutation (SNP) | VAF 66/266 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs756429998, COSV99942846; called by muse, mutect2, varscan2
- FGD1 | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 46/536 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.18); catalogued as COSV64309820; called by muse, mutect2
- FLACC1 | c.782dup p.M262Dfs*14 | Frame Shift Ins (INS) | VAF 28/168 reads (17%) | catalogued as rs761500161; called by mutect2, varscan2
- FMR1 | c.1610del p.G537Efs*92 | Frame Shift Del (DEL) | VAF 67/283 reads (24%) | catalogued as COSV99503749; called by mutect2, pindel, varscan2
- FRAS1 | c.2018G>A p.C673Y | Missense Mutation (SNP) | VAF 65/193 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99355174; called by muse, mutect2, varscan2
- FRMD4A | c.2740G>A p.A914T | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0.051); catalogued as COSV62267437; called by muse, mutect2, varscan2
- FRY | c.4889C>T p.T1630I | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1430739144; called by muse, mutect2, varscan2
- GPR180 | c.9del p.L4_?3 | Frame Shift Del (DEL) | VAF 47/188 reads (25%) | catalogued as rs772740445; called by mutect2, pindel, varscan2
- GRIN2D | c.2087G>A p.R696H | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.717); catalogued as rs1252266807; called by muse, mutect2, varscan2
- GSK3A | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as rs1337074844, COSV55901112; called by muse, mutect2, varscan2
- HDGFL2 | c.677del p.K226Rfs*45 | Frame Shift Del (DEL) | VAF 30/152 reads (20%) | catalogued as rs1219916331, COSV56682191; called by mutect2, varscan2
- HELZ | c.4756C>T p.R1586C | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); catalogued as rs1254150127, COSV62379964; called by muse, mutect2
- HERC2 | c.2701G>A p.A901T | Missense Mutation (SNP) | VAF 164/420 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs939625848, COSV55315987; called by muse, mutect2, varscan2
- HMX1 | c.419C>T p.T140M | Missense Mutation (SNP) | VAF 10/183 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.301); catalogued as rs1031498533; called by muse, mutect2
- HNRNPL | c.1010del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 9/54 reads (17%) | catalogued as rs767148651; called by mutect2, varscan2
- IGSF9B | c.2618G>A p.R873H | Missense Mutation (SNP) | VAF 70/285 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs769756373, COSV58071775; called by muse, mutect2, varscan2
- IL17RA | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 39/647 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.961); catalogued as rs777319486, COSV60055942; called by muse, mutect2
- IL6R | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs201340163; called by muse, mutect2, varscan2
- INPPL1 | c.3049G>A p.V1017M | Missense Mutation (SNP) | VAF 34/402 reads (8%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.969); catalogued as rs778573534; called by muse, mutect2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 31/144 reads (22%) | catalogued as rs760925109; called by pindel, varscan2
- INPPL1 | c.3470del p.G1157Dfs*45 | Frame Shift Del (DEL) | VAF 26/126 reads (21%) | catalogued as rs1565399032, COSV53356328, COSV99996061; called by pindel, varscan2
- IRX4 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 134/372 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770961282, COSV51474480, COSV51475669; called by muse, varscan2
- ITGA5 | c.1003G>A p.V335I | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs762335174, COSV53219693; called by muse, mutect2, varscan2
- ITGB7 | c.1906G>A p.D636N | Missense Mutation (SNP) | VAF 84/261 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as rs558739649, COSV57239528; called by muse, mutect2, varscan2
- ITPR1 | c.58G>T p.E20* | Nonsense Mutation (SNP) | VAF 61/258 reads (24%) | catalogued as COSV100231880; called by muse, mutect2, varscan2
- JPH4 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 140/455 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as rs371600479; called by muse, mutect2, varscan2
- KBTBD4 | c.1156del p.E386Rfs*27 | Frame Shift Del (DEL) | VAF 156/642 reads (24%) | catalogued as rs756343868; called by mutect2, varscan2
- KBTBD4 | c.796A>G p.S266G | Missense Mutation (SNP) | VAF 63/218 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as rs1241786492; called by muse, mutect2, varscan2
- KIAA1109 | c.4770del p.K1590Nfs*11 | Frame Shift Del (DEL) | VAF 22/64 reads (34%) | catalogued as rs779140281, COSV52689741; called by mutect2, varscan2
- KIAA1109 | c.9568C>T p.R3190* | Nonsense Mutation (SNP) | VAF 73/265 reads (28%) | catalogued as rs1186567070, COSV52691509; called by muse, mutect2, varscan2
- KLK1 | c.42dup p.T15Dfs*18 | Frame Shift Ins (INS) | VAF 30/93 reads (32%) | catalogued as rs758242614; called by mutect2, varscan2
- KLRK1 | c.164del p.F55Sfs*7 | Frame Shift Del (DEL) | VAF 50/150 reads (33%) | catalogued as rs756606329, COSV53699502; called by mutect2, varscan2
- KRT28 | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 79/216 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV60685085; called by muse, mutect2, varscan2
- L1CAM | c.3281G>T p.R1094M | Missense Mutation (SNP) | VAF 72/360 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100649343; called by muse, mutect2, varscan2
- LAMB3 | c.22T>A p.C8S | Missense Mutation (SNP) | VAF 170/560 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1450626807; called by muse, mutect2, varscan2
- LCE2B | c.52C>A p.P18T | Missense Mutation (SNP) | VAF 74/211 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.958); catalogued as COSV64227608; called by muse, mutect2, varscan2
- LDB1 | c.377G>A p.R126H (on ENST00000425280 / NM_001321612.2; = p.R90H on NM_003893.5) | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs757787986, COSV104419389, COSV63289556; called by muse, mutect2
- LPIN3 | c.2420G>A p.R807Q | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs371258106; called by muse, mutect2, varscan2
- LRP3 | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.372); catalogued as rs762014338; called by muse, mutect2, varscan2
- LRRC37B | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 120/578 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs778576380; called by muse, mutect2, varscan2
- LRRTM4 | c.1720A>G p.T574A | Missense Mutation (SNP) | VAF 31/503 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as rs1283521143, COSV69174218; called by muse, mutect2
- LUC7L3 | c.1165del p.S389Vfs*3 | Frame Shift Del (DEL) | VAF 27/107 reads (25%) | catalogued as rs1229438198; called by mutect2, pindel, varscan2
- LYN | c.327del p.E110Kfs*15 | Frame Shift Del (DEL) | VAF 77/236 reads (33%) | catalogued as rs1266824391, COSV99066642; called by mutect2, pindel, varscan2
- MAGEL2 | c.1784C>T p.P595L | Missense Mutation (SNP) | VAF 93/318 reads (29%) | SIFT deleterious, low confidence (0.03); catalogued as rs1256362315, COSV100045897; called by muse, mutect2, varscan2
- MAP3K14 | c.115G>A p.V39I | Missense Mutation (SNP) | VAF 155/456 reads (34%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs571893035, COSV100766380; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAP3K4 | c.479del p.N160Mfs*8 | Frame Shift Del (DEL) | VAF 67/225 reads (30%) | catalogued as COSV62334603; called by mutect2, varscan2
- MARK3 | c.1685G>A p.R562H | Missense Mutation (SNP) | VAF 18/466 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV53507561; called by muse, mutect2
- MBD1 | c.1123C>T p.R375C (on ENST00000269468 / NM_001323950.1; = p.R352C on NM_015845.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 148/556 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54000042; called by muse, mutect2, varscan2
- MBOAT4 | c.1049G>A p.C350Y | Missense Mutation (SNP) | VAF 101/379 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as COSV57643258; called by muse, mutect2, varscan2
- METTL21C | c.520del p.E174Kfs*18 | Frame Shift Del (DEL) | VAF 87/375 reads (23%) | catalogued as rs760847518; called by mutect2, pindel, varscan2
- MGST3 | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 139/417 reads (33%) | catalogued as rs1344400013; called by muse, varscan2
- MIDEAS | c.924del p.Y309Tfs*9 | Frame Shift Del (DEL) | VAF 10/43 reads (23%) | catalogued as COSV99679261; called by mutect2, pindel, varscan2
- MLLT6 | c.2182G>A p.A728T | Missense Mutation (SNP) | VAF 18/361 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.517); catalogued as rs1466745487; called by muse, mutect2
- MMRN1 | c.2646del p.G883Afs*3 | Frame Shift Del (DEL) | VAF 41/162 reads (25%) | catalogued as rs750319971; called by mutect2, pindel, varscan2
- MNT | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 17/290 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV51512744; called by muse, mutect2
- MPRIP | c.1058dup p.A354Sfs*43 | Frame Shift Ins (INS) | VAF 13/55 reads (24%) | catalogued as rs778181735; called by mutect2, varscan2
- MRPL45 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755977222; called by muse, mutect2, varscan2
- MX2 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 104/367 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); catalogued as rs749482420, COSV58098973; called by muse, mutect2, varscan2
- MYO1H | c.1694C>T p.A565V | Missense Mutation (SNP) | VAF 58/232 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.341); catalogued as COSV100183208; called by muse, mutect2, varscan2
- MYO3B | c.3671G>A p.R1224Q | Missense Mutation (SNP) | VAF 19/336 reads (6%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs750028664, COSV100508841, COSV58707708; called by muse, mutect2
- MYO7A | c.5122C>T p.R1708C | Missense Mutation (SNP) | VAF 90/279 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs529974676, CM140897, COSV68684586; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO9B | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 176/560 reads (31%) | SIFT tolerated (0.76); PolyPhen benign (0.017); catalogued as rs552671478, COSV68280984; called by muse, mutect2, varscan2
- NCOA2 | c.1820G>A p.G607E | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs777565659; called by muse, mutect2
- NEB | c.9263G>A p.S3088N | Missense Mutation (SNP) | VAF 200/690 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV99416209; called by muse, mutect2, varscan2
- NFATC1 | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs924224430; called by muse, mutect2, varscan2
- NGRN | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 82/229 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.266); catalogued as rs1304181223; called by muse, mutect2
- NKPD1 | c.1910A>T p.Q637L | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.055); catalogued as rs749449338; called by muse, mutect2, varscan2
- NLRP10 | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 94/265 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs772428914, COSV60782805; called by muse, mutect2, varscan2
- NLRP8 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 76/225 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.879); catalogued as rs145352424, COSV52585687; called by muse, mutect2, varscan2
- NSMCE3 | c.597G>T p.W199C | Missense Mutation (SNP) | VAF 11/299 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54269994, COSV99721103; called by muse, mutect2
- NSRP1 | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 55/224 reads (25%) | catalogued as rs766687348; called by muse, mutect2, varscan2
- NUP214 | c.681del p.V228Sfs*29 | Frame Shift Del (DEL) | VAF 37/138 reads (27%) | catalogued as rs771913112, COSV63912486; called by mutect2, varscan2
- OBSCN | c.13778G>A p.R4593H | Missense Mutation (SNP) | VAF 123/450 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as rs375018093; called by muse, mutect2, varscan2
- OXLD1 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100235660; called by muse, mutect2
- PAFAH1B1 | c.1172C>T p.T391M | Missense Mutation (SNP) | VAF 37/208 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.525); catalogued as rs757892852; called by muse, mutect2, varscan2
- PAN2 | c.1576G>A p.A526T | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as rs1416365335, COSV57752500; called by muse, mutect2, varscan2
- PASD1 | c.2312A>G p.K771R | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.138); catalogued as rs976609620, COSV64855577; called by muse, mutect2
- PCDH8 | c.2356del p.A786Pfs*151 | Frame Shift Del (DEL) | VAF 17/91 reads (19%) | catalogued as rs770663005, COSV100131664; called by mutect2, pindel, varscan2
- PCDHB10 | c.2060T>C p.L687S | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs534521900; called by muse, mutect2, varscan2
- PCNX2 | c.2356C>T p.R786W | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs760662776; called by muse, mutect2, varscan2
- PCSK1 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 111/464 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs753488725, COSV60736381, COSV60737254; called by muse, mutect2, varscan2
- PCSK6 | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 102/350 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.929); catalogued as rs374933240; called by muse, mutect2, varscan2
- PDE1C | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 45/242 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs1392425874; called by muse, mutect2, varscan2
- PDS5B | c.4169del p.N1390Mfs*4 | Frame Shift Del (DEL) | VAF 46/110 reads (42%) | catalogued as rs759495724; called by mutect2, varscan2
- PHF2 | c.1475dup p.T493Dfs*21 | Frame Shift Ins (INS) | VAF 28/144 reads (19%) | catalogued as rs769717544; called by mutect2, varscan2
- PIGB | c.840del p.F280Lfs*12 | Frame Shift Del (DEL) | VAF 74/214 reads (35%) | catalogued as rs756552559; called by mutect2, varscan2
- PKN1 | c.1740del p.I581Sfs*25 | Frame Shift Del (DEL) | VAF 25/288 reads (9%) | catalogued as rs1386022300, COSV99466526; called by mutect2, pindel
- PLB1 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 116/352 reads (33%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs367544358; called by muse, mutect2, varscan2
- PLEKHH1 | c.4019G>A p.C1340Y | Missense Mutation (SNP) | VAF 26/503 reads (5%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as rs746162181; called by muse, mutect2
- PLEKHH3 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 28/361 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as rs868382997, COSV52216735; called by muse, mutect2
- POLR3A | c.1609C>T p.P537S | Missense Mutation (SNP) | VAF 153/679 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV64932027; called by muse, mutect2, varscan2
- POU3F4 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 127/341 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as rs1219887341, COSV64538135; called by muse, mutect2, varscan2
- PPP1CA | c.491T>C p.I164T | Missense Mutation (SNP) | VAF 77/345 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.55); catalogued as rs1307229649; called by muse, mutect2, varscan2
- PRELP | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 107/351 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs760198476, COSV58117608; called by muse, mutect2, varscan2
- PREX2 | c.1693dup p.S565Ffs*3 | Frame Shift Ins (INS) | VAF 75/281 reads (27%) | catalogued as rs764112302; called by mutect2, varscan2
- PRKAG2 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 198/566 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.9); catalogued as rs41317142, COSV55232567; ClinVar: uncertain significance; called by mutect2, varscan2
- PROCR | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 21/268 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.265); catalogued as rs767883054; called by muse, mutect2
- PRR16 | c.830del p.P277Lfs*20 (on ENST00000407149 / NM_001300783.2; = p.P254Lfs*20 on NM_016644.2) | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | catalogued as COSV65401020; called by mutect2, pindel, varscan2
- RALGAPA1 | c.2950A>G p.T984A | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs777104934; called by muse, mutect2
- RAPGEF1 | c.1846C>T p.R616W | Missense Mutation (SNP) | VAF 22/340 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs1039814378; called by muse, mutect2
- RFX1 | c.2784_2786del p.E932del | In Frame Del (DEL) | VAF 28/145 reads (19%) | catalogued as rs922670319; called by pindel, varscan2
- RGMA | c.1300C>G p.P434A | Missense Mutation (SNP) | VAF 17/274 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1230832575, COSV100224292; called by muse, mutect2
- RHOBTB2 | c.325A>G p.I109V | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.765); catalogued as COSV52573594; called by muse, mutect2, varscan2
- RHOXF2B | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 56/240 reads (23%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.892); catalogued as COSV65054921; called by mutect2, varscan2
- RIMS2 | c.3704C>T p.S1235L | Missense Mutation (SNP) | VAF 15/201 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.743); catalogued as rs374441699; called by muse, mutect2
- RNF128 | c.31del p.W11Gfs*4 | Frame Shift Del (DEL) | VAF 26/62 reads (42%) | catalogued as rs757038390; called by mutect2, varscan2
- ROBO3 | c.571del p.R191Afs*31 | Frame Shift Del (DEL) | VAF 74/232 reads (32%) | catalogued as rs756837590; ClinVar: uncertain significance; called by mutect2, varscan2
- RP1 | c.4268G>T p.C1423F | Missense Mutation (SNP) | VAF 92/312 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs752205338; called by muse, mutect2, varscan2
- RPL22 | c.44dup p.K16Efs*9 | Frame Shift Ins (INS) | VAF 82/342 reads (24%) | catalogued as rs759765382; called by mutect2, varscan2
- RSC1A1 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 12/221 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.066); catalogued as rs1172622842; called by muse, mutect2
- RTN1 | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 30/289 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV99955739; called by muse, mutect2, varscan2
- RYR1 | c.3923C>T p.P1308L | Missense Mutation (SNP) | VAF 18/544 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs1240408895, COSV100615352; called by muse, mutect2
- SCAF4 | c.1955C>G p.T652R | Missense Mutation (SNP) | VAF 91/285 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.112); catalogued as rs1353918086; called by muse, mutect2, varscan2
- SCN11A | c.1472del p.K491Sfs*5 | Frame Shift Del (DEL) | VAF 26/109 reads (24%) | catalogued as rs765136101; called by mutect2, pindel, varscan2
- SEC16B | c.1299del p.S434Vfs*29 | Frame Shift Del (DEL) | VAF 20/97 reads (21%) | catalogued as rs768388757; called by mutect2, pindel, varscan2
- SF3A1 | c.1532G>A p.R511Q | Missense Mutation (SNP) | VAF 20/381 reads (5%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.885); catalogued as COSV53167149, COSV53168723; called by muse, mutect2
- SH2B2 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 58/184 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as rs782719204, COSV60827748; called by muse, mutect2, varscan2
- SLC12A3 | c.1336-1G>T p.X446_splice | Splice Site (SNP) | VAF 84/357 reads (24%) | catalogued as CS117010; called by muse, mutect2, varscan2
- SLC20A1 | c.1943G>A p.R648H | Missense Mutation (SNP) | VAF 104/372 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755784156, COSV55610450; called by muse, mutect2, varscan2
- SLC22A12 | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 161/431 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1014455077; called by muse, mutect2, varscan2
- SLC4A5 | c.3267del p.A1091Pfs*17 | Frame Shift Del (DEL) | VAF 36/145 reads (25%) | catalogued as rs1558864722; called by mutect2, pindel, varscan2
- SLC6A20 | c.325G>C p.A109P | Missense Mutation (SNP) | VAF 59/260 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as rs1365319225; called by muse, mutect2, varscan2
- SLITRK3 | c.2891C>T p.P964L | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs748456407, COSV53846864, COSV53847822; called by muse, mutect2, varscan2
- SLITRK3 | c.500G>T p.G167V | Missense Mutation (SNP) | VAF 11/291 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99578179; called by muse, mutect2
- SNRPA1 | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs369821067; called by muse, mutect2
- SPEG | c.9365C>T p.T3122M | Missense Mutation (SNP) | VAF 75/194 reads (39%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.921); catalogued as rs200200624; called by muse, mutect2, varscan2
- SPEG | c.9586C>T p.R3196* | Nonsense Mutation (SNP) | VAF 60/181 reads (33%) | catalogued as rs746906014, COSV56664366; called by muse, mutect2, varscan2
- SSU72P8 | c.71G>C p.S24T | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.081); catalogued as COSV66361414; called by muse, mutect2, varscan2
- SYNM | c.4033G>A p.G1345R | Missense Mutation (SNP) | VAF 26/321 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs180787652; called by muse, mutect2
- TARM1 | c.340del p.H114Tfs*14 (on ENST00000616041 / NM_001330650.1; = p.H106Tfs*14 on NM_001135686.3) | Frame Shift Del (DEL) | VAF 73/254 reads (29%) | catalogued as rs773860043; called by mutect2, pindel, varscan2
- TASOR2 | c.5195C>G p.T1732R | Missense Mutation (SNP) | VAF 111/308 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.045); catalogued as COSV60168038; called by muse, mutect2, varscan2
- TET3 | c.3665C>T p.P1222L | Missense Mutation (SNP) | VAF 79/357 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs368750647; called by muse, mutect2, varscan2
- TEX51 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious, low confidence (0.03); catalogued as rs987338546; called by muse, mutect2
- TLR9 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs147453407; called by muse, mutect2, varscan2
- TMEM132A | c.1480del p.L494Cfs*82 (on ENST00000453848 / NM_178031.3; = p.L495Cfs*82 on NM_017870.4) | Frame Shift Del (DEL) | VAF 106/448 reads (24%) | catalogued as COSV50001098; called by mutect2, pindel, varscan2
- TMEM178B | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 13/323 reads (4%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.554); catalogued as rs1357734081; called by muse, mutect2
- TNR | c.871G>T p.D291Y | Missense Mutation (SNP) | VAF 111/340 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs762411728; called by muse, mutect2, varscan2
- TNRC6A | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 200/578 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as rs758756773, COSV59363579; called by muse, mutect2, varscan2
- TNRC6B | c.3721A>G p.M1241V (on ENST00000454349 / NM_001162501.2; = p.M1131V on NM_015088.3) | Missense Mutation (SNP) | VAF 73/208 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs748168282; called by muse, mutect2, varscan2
- TP53I11 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 16/173 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777312022; called by muse, mutect2
- TRAK1 | c.599C>A p.S200* (on ENST00000327628 / NM_001349247.2; = p.S142* on NM_014965.5) | Nonsense Mutation (SNP) | VAF 38/165 reads (23%) | catalogued as rs766246712, COSV58257829; called by muse, mutect2, varscan2
- TRIM10 | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 152/588 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.79); catalogued as COSV64994073; called by muse, mutect2, varscan2
- TRIOBP | c.4109A>C p.Q1370P | Missense Mutation (SNP) | VAF 93/305 reads (30%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs890718506; called by muse, mutect2, varscan2
- TRPV3 | c.1669C>A p.L557M | Missense Mutation (SNP) | VAF 34/427 reads (8%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.995); catalogued as COSV100028305; called by muse, mutect2
- TSPAN11 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs145395262; called by muse, mutect2, varscan2
- TSPYL4 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 92/368 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.581); catalogued as rs755700789; called by muse, mutect2, varscan2
- TTC37 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 13/228 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs1033302823, COSV62453770; called by muse, mutect2
- TUT7 | c.161del p.K54Rfs*3 | Frame Shift Del (DEL) | VAF 111/459 reads (24%) | catalogued as rs369091628; called by mutect2, pindel, varscan2
- UMOD | c.430del p.D144Mfs*100 | Frame Shift Del (DEL) | VAF 100/390 reads (26%) | catalogued as rs775408588, COSV56774247; called by mutect2, pindel, varscan2
- UNCX | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs1256609471; called by muse, mutect2
- VSIG2 | c.297dup p.T100Hfs*11 | Frame Shift Ins (INS) | VAF 112/356 reads (31%) | catalogued as rs766405238; called by mutect2, varscan2
- VWF | c.1668del p.H556Qfs*21 | Frame Shift Del (DEL) | VAF 19/201 reads (9%) | catalogued as CD1310899; called by mutect2, pindel, varscan2
- WDR31 | c.1039G>T p.G347* (on ENST00000374193 / NM_001006615.3; = p.G346* on NM_145241.5) | Nonsense Mutation (SNP) | VAF 54/220 reads (25%) | catalogued as rs765680364, COSV59145873; called by muse, mutect2, varscan2
- WDR93 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1415870857, COSV51533803; called by muse, mutect2, varscan2
- XYLT2 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 72/221 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.446); catalogued as rs1269565488; called by muse, mutect2, varscan2
- ZBED6CL | c.314A>G p.Y105C | Missense Mutation (SNP) | VAF 54/214 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); catalogued as COSV100550320; called by muse, mutect2, varscan2
- ZFHX3 | c.7666_7667insGG p.A2556Gfs*57 | Frame Shift Ins (INS) | VAF 102/412 reads (25%) | catalogued as COSV99213910; called by pindel, varscan2
- ZFP90 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1432412133, COSV68051157; called by muse, mutect2, varscan2
- ZNF106 | c.1444del p.S482Pfs*33 | Frame Shift Del (DEL) | VAF 87/285 reads (31%) | catalogued as rs1198467282, COSV55516091; called by mutect2, varscan2
- ZNF182 | c.1559G>A p.G520D | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as rs868971867, COSV59358150; called by muse, mutect2, varscan2
- ZNF197 | c.1495G>A p.D499N | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.939); catalogued as rs748787727; called by muse, mutect2, varscan2
- ZNF248 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 57/194 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs773079791; called by muse, mutect2, varscan2
- ZNF311 | c.352C>T p.R118* | Nonsense Mutation (SNP) | VAF 91/284 reads (32%) | catalogued as rs149098069; called by muse, mutect2, varscan2
- ZNF536 | c.3809C>A p.A1270D | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as rs766906828, COSV62836005; called by muse, mutect2, varscan2
- ZNF800 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 44/195 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1399951318, COSV56175067, COSV99757947; called by muse, mutect2, varscan2
- ABCC9 | c.803A>G p.Y268C | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ABCF1 | c.1456G>A p.A486T (on ENST00000326195 / NM_001025091.2; = p.A448T on NM_001090.3) | Missense Mutation (SNP) | VAF 113/402 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRV1 | c.7384del p.Q2462Sfs*5 | Frame Shift Del (DEL) | VAF 104/393 reads (26%) | called by mutect2, pindel, varscan2
- ADO | c.271T>C p.Y91H | Missense Mutation (SNP) | VAF 85/419 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- AGPAT1 | c.559A>G p.M187V | Missense Mutation (SNP) | VAF 134/560 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- AGPS | c.1598C>A p.P533H | Missense Mutation (SNP) | VAF 107/351 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AGRN | c.2218C>T p.R740* | Nonsense Mutation (SNP) | VAF 108/417 reads (26%) | called by muse, mutect2, varscan2
- AHNAK2 | c.9970G>T p.G3324C | Missense Mutation (SNP) | VAF 70/934 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- AJM1 | c.992T>C p.V331A | Missense Mutation (SNP) | VAF 191/524 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); called by mutect2, varscan2
- AKAP9 | c.5573T>C p.V1858A (on ENST00000359028; = p.V1826A on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/452 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- AL592490.1 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 70/230 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- AMER1 | c.2018C>A p.T673N | Missense Mutation (SNP) | VAF 21/345 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.021); called by muse, mutect2
- ANGEL1 | c.1304A>T p.N435I | Missense Mutation (SNP) | VAF 75/293 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKH | c.775A>G p.N259D | Missense Mutation (SNP) | VAF 134/539 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ANKRD63 | c.250G>T p.G84C | Missense Mutation (SNP) | VAF 141/415 reads (34%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- ARHGAP35 | c.4304T>G p.F1435C | Missense Mutation (SNP) | VAF 119/338 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF18 | c.2611C>T p.R871C (on ENST00000359920 / NM_001130955.2; = p.R767C on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/351 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARID5B | c.1460dup p.L488Sfs*40 | Frame Shift Ins (INS) | VAF 24/92 reads (26%) | called by mutect2, pindel, varscan2
- ATP7B | c.2897T>C p.V966A | Missense Mutation (SNP) | VAF 60/427 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- B3GNTL1 | c.524C>A p.P175H | Missense Mutation (SNP) | VAF 67/296 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BAHCC1 | c.6368G>A p.G2123D | Missense Mutation (SNP) | VAF 29/559 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); called by muse, mutect2
- BTRC | c.558dup p.R187Sfs*8 (on ENST00000370187 / NM_033637.4; = p.R151Sfs*8 on NM_003939.5) | Frame Shift Ins (INS) | VAF 30/108 reads (28%) | called by mutect2, pindel, varscan2
- BUB1 | c.542A>G p.N181S | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- C8orf74 | c.776T>C p.L259P | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CAST | c.1030G>T p.A344S (on ENST00000341926; = p.A427S on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CBY3 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- CCDC107 | c.400del p.L134Ffs*5 | Frame Shift Del (DEL) | VAF 115/445 reads (26%) | called by mutect2, pindel, varscan2
- CD40LG | c.59G>A p.S20N | Missense Mutation (SNP) | VAF 151/470 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CELSR1 | c.1841del p.G614Afs*54 | Frame Shift Del (DEL) | VAF 31/162 reads (19%) | called by mutect2, varscan2
- CENPJ | c.3472G>A p.G1158R | Missense Mutation (SNP) | VAF 65/306 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CEP295 | c.2950A>G p.R984G | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP76 | c.419T>C p.L140S | Missense Mutation (SNP) | VAF 19/256 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- CERS1 | c.592T>C p.Y198H | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2
- CERS3 | c.998A>G p.K333R | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- CHD3 | c.4800del p.S1601Afs*17 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | called by mutect2, pindel, varscan2
- CHD9 | c.2280del p.F760Lfs*16 | Frame Shift Del (DEL) | VAF 40/172 reads (23%) | called by mutect2, pindel, varscan2
- CHRNA4 | c.1076A>T p.K359M | Missense Mutation (SNP) | VAF 22/674 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); called by muse, mutect2
- CHST13 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.825); called by muse, mutect2
- CLCN1 | c.1582+2T>C p.X528_splice | Splice Site (SNP) | VAF 16/320 reads (5%) | called by muse, mutect2
- CNTN4 | c.2123G>T p.G708V | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CNTNAP2 | c.1616G>T p.R539M | Missense Mutation (SNP) | VAF 81/242 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- COL5A1 | c.1569+2T>C p.X523_splice | Splice Site (SNP) | VAF 149/661 reads (23%) | called by muse, mutect2, varscan2
- COX7B2 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COX7C | c.*28-1G>C | Splice Site (SNP) | VAF 18/64 reads (28%) | called by muse, mutect2, varscan2
- CRKL | c.821A>T p.Q274L | Missense Mutation (SNP) | VAF 16/335 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- CSMD1 | c.8923G>T p.E2975* (on ENST00000520002; = p.E2974* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 38/150 reads (25%) | called by muse, varscan2
- CSRP1 | c.533A>G p.K178R | Missense Mutation (SNP) | VAF 19/316 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- CTNNBL1 | c.218A>C p.E73A | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.096); called by muse, varscan2
- CYP21A2 | c.1151T>C p.V384A | Missense Mutation (SNP) | VAF 179/971 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- DAO | c.680del p.P227Rfs*24 | Frame Shift Del (DEL) | VAF 133/587 reads (23%) | called by mutect2, pindel, varscan2
- DBNL | c.1043dup p.L349Tfs*10 (on ENST00000448521 / NM_001014436.3; = p.L350Tfs*10 on NM_014063.7) | Frame Shift Ins (INS) | VAF 52/185 reads (28%) | called by mutect2, pindel, varscan2
- DDI1 | c.256G>T p.G86W | Missense Mutation (SNP) | VAF 111/413 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- DDX53 | c.1042A>T p.I348F | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DIP2C | c.725T>C p.M242T | Missense Mutation (SNP) | VAF 14/368 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.01); called by muse, mutect2
- DLGAP1 | c.1675G>A p.A559T | Missense Mutation (SNP) | VAF 160/425 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- DNAH14 | c.2530A>G p.S844G (on ENST00000445597; = p.S910G on NM_001367479.1) | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH8 | c.755T>C p.L252P | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAH9 | c.7540G>A p.A2514T | Missense Mutation (SNP) | VAF 11/297 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.314); called by muse, mutect2
- DNHD1 | c.10016C>T p.A3339V | Missense Mutation (SNP) | VAF 101/330 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- DSG1 | c.1688-3C>A | Splice Region (SNP) | VAF 185/567 reads (33%) | called by muse, mutect2, varscan2
- EFTUD2 | c.1081C>A p.P361T | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- EGFL6 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 15/413 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.045); called by muse, mutect2
- EGFL7 | c.424A>G p.S142G | Missense Mutation (SNP) | VAF 13/330 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.197); called by muse, mutect2
- ELAPOR1 | c.2971A>G p.K991E | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.085); called by muse, mutect2
- ELAVL1 | c.228_229del p.R76Sfs*16 | Frame Shift Del (DEL) | VAF 99/462 reads (21%) | called by pindel, varscan2
- ERN2 | c.1399dup p.L467Pfs*42 | Frame Shift Ins (INS) | VAF 32/138 reads (23%) | called by mutect2, pindel, varscan2
- EXOC5 | c.1745A>G p.Y582C | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- FAM160B2 | c.363C>A p.H121Q | Missense Mutation (SNP) | VAF 26/387 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.055); called by muse, mutect2
- FAM83H | c.1534C>T p.P512S | Missense Mutation (SNP) | VAF 19/282 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.906); called by muse, mutect2
- FAM8A1 | c.112T>C p.C38R | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); called by muse, mutect2
- FAT3 | c.2777dup p.L926Ffs*3 | Frame Shift Ins (INS) | VAF 84/236 reads (36%) | called by mutect2, varscan2
- FKBP6 | c.830T>G p.V277G | Missense Mutation (SNP) | VAF 142/555 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- FLNC | c.76_78del p.K26del | In Frame Del (DEL) | VAF 150/445 reads (34%) | called by mutect2, pindel, varscan2
- FSCB | c.1631C>A p.S544Y | Missense Mutation (SNP) | VAF 55/216 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- FTHL17 | c.116C>A p.A39D | Missense Mutation (SNP) | VAF 111/393 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GABRG2 | c.1435G>T p.A479S (on ENST00000361925 / NM_001375343.1; = p.A439S on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 126/469 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- GDF1 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated, low confidence (0.05); called by muse, mutect2, varscan2
- GIGYF2 | c.2605G>T p.E869* | Nonsense Mutation (SNP) | VAF 132/553 reads (24%) | called by muse, mutect2, varscan2
- GK3P | c.1494del p.R499Vfs*9 | Frame Shift Del (DEL) | VAF 74/221 reads (33%) | called by mutect2, varscan2
- GLMP | c.931_932del p.Y311Lfs*17 | Frame Shift Del (DEL) | VAF 193/697 reads (28%) | called by mutect2, pindel, varscan2
- GMEB2 | c.1523C>G p.A508G | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- GMPPA | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- GNA15 | c.125A>C p.E42A | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GRK5 | c.1098del p.D367Tfs*12 | Frame Shift Del (DEL) | VAF 67/276 reads (24%) | called by mutect2, pindel, varscan2
- GUCY1A2 | c.1792del p.E598Nfs*7 | Frame Shift Del (DEL) | VAF 55/253 reads (22%) | called by mutect2, pindel, varscan2
- GYPB | c.271-1G>T p.X91_splice | Splice Site (SNP) | VAF 13/324 reads (4%) | called by muse, mutect2
- H1-8 | c.883C>G p.P295A | Missense Mutation (SNP) | VAF 111/347 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- HAO2 | c.890T>A p.I297N | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- HERC2 | c.6614C>T p.A2205V | Missense Mutation (SNP) | VAF 33/662 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- HEXIM2 | c.556G>T p.G186C | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- HMCN2 | c.13639C>T p.Q4547* | Nonsense Mutation (SNP) | VAF 158/505 reads (31%) | called by muse, varscan2
- HNF1B | c.1304T>C p.M435T | Missense Mutation (SNP) | VAF 34/440 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- HNRNPUL1 | c.1218T>A p.S406R | Missense Mutation (SNP) | VAF 15/238 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.053); called by muse, mutect2
- HNRNPUL1 | c.1366A>G p.N456D | Missense Mutation (SNP) | VAF 90/300 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- HRC | c.188G>A p.S63N | Missense Mutation (SNP) | VAF 18/398 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- ITGB7 | c.566T>C p.V189A | Missense Mutation (SNP) | VAF 133/466 reads (29%) | SIFT tolerated (0.93); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- JAK1 | c.2377C>T p.P793S | Missense Mutation (SNP) | VAF 84/233 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JSRP1 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 60/167 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNC4 | c.66A>T p.K22N | Missense Mutation (SNP) | VAF 92/280 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- KDR | c.344A>T p.Y115F | Missense Mutation (SNP) | VAF 34/462 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- KIAA1217 | c.3324G>A p.W1108* | Nonsense Mutation (SNP) | VAF 40/150 reads (27%) | called by muse, varscan2
- KIF20B | c.989del p.L330* | Frame Shift Del (DEL) | VAF 47/190 reads (25%) | called by mutect2, pindel, varscan2
- KRT25 | c.1307_1310del p.L436Pfs*? | Frame Shift Del (DEL) | VAF 58/238 reads (24%) | called by mutect2, pindel, varscan2
- KRT33A | c.326C>T p.T109I | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- KRT74 | c.627G>T p.R209S | Missense Mutation (SNP) | VAF 19/704 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2
- KRTAP10-10 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 173/613 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- KRTAP19-4 | c.49G>T p.G17C | Missense Mutation (SNP) | VAF 111/325 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LGALS4 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LILRB3 | c.575G>T p.W192L | Missense Mutation (SNP) | VAF 98/506 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- LINGO3 | c.773T>G p.I258S | Missense Mutation (SNP) | VAF 155/438 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- LTB4R | c.179T>G p.L60R | Missense Mutation (SNP) | VAF 21/226 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAPKAPK5 | c.468del p.F156Lfs*10 | Frame Shift Del (DEL) | VAF 31/108 reads (29%) | called by mutect2, pindel, varscan2
- ME2 | c.459T>A p.N153K | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MRPL39 | c.988A>T p.K330* | Nonsense Mutation (SNP) | VAF 63/194 reads (32%) | called by muse, mutect2, varscan2
- MRPL4 | c.754A>C p.S252R | Missense Mutation (SNP) | VAF 65/248 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MSANTD2 | c.1675A>G p.N559D (on ENST00000374979 / NM_001308027.2; = p.N507D on NM_024631.4) | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MTSS2 | c.1677del p.G560Afs*34 | Frame Shift Del (DEL) | VAF 44/114 reads (39%) | called by mutect2, pindel, varscan2
- MYCT1 | c.86del p.F29Sfs*28 | Frame Shift Del (DEL) | VAF 24/151 reads (16%) | called by mutect2, pindel, varscan2
- NAA30 | c.1058A>G p.D353G | Missense Mutation (SNP) | VAF 11/193 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2
- NEMP1 | c.359del p.L120* | Frame Shift Del (DEL) | VAF 102/355 reads (29%) | called by mutect2, pindel, varscan2
- NPAS3 | c.2289_2306del p.G767_G772del (on ENST00000356141 / NM_001164749.2; = p.G735_G740del on NM_022123.3) | In Frame Del (DEL) | VAF 52/81 reads (64%) | called by mutect2, pindel, varscan2
- NR5A2 | c.250G>T p.E84* (on ENST00000367362 / NM_205860.3; = p.E38* on NM_003822.5) | Nonsense Mutation (SNP) | VAF 47/192 reads (24%) | called by muse, mutect2, varscan2
- NSD1 | c.4591del p.M1531Cfs*43 | Frame Shift Del (DEL) | VAF 142/678 reads (21%) | called by pindel, varscan2
- NYAP1 | c.1540dup p.H514Pfs*52 | Frame Shift Ins (INS) | VAF 36/221 reads (16%) | called by mutect2, pindel, varscan2
- OGT | c.249dup p.Q84Tfs*27 | Frame Shift Ins (INS) | VAF 21/211 reads (10%) | called by mutect2, pindel
- OR11L1 | c.454G>T p.G152W | Missense Mutation (SNP) | VAF 32/518 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR2T11 | c.851C>A p.P284H | Missense Mutation (SNP) | VAF 21/475 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- OR56A3 | c.451T>A p.F151I | Missense Mutation (SNP) | VAF 146/472 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5H15 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 108/411 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OR5J2 | c.907del p.R303Gfs*3 | Frame Shift Del (DEL) | VAF 25/115 reads (22%) | called by mutect2, pindel, varscan2
- OR6K2 | c.911del p.K304Sfs*3 | Frame Shift Del (DEL) | VAF 37/148 reads (25%) | called by mutect2, pindel, varscan2
- OSBP2 | c.1609A>G p.R537G | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.155); called by muse, mutect2
- OSBPL1A | c.2682del p.K894Nfs*71 (on ENST00000319481 / NM_080597.4; = p.K381Nfs*71 on NM_018030.4) | Frame Shift Del (DEL) | VAF 65/242 reads (27%) | called by mutect2, varscan2
- OTOGL | c.6593del p.N2198Mfs*9 (on ENST00000547103; = p.N2189Mfs*9 on NM_173591.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 37/152 reads (24%) | called by mutect2, pindel, varscan2
- OTUD7A | c.545A>G p.Q182R | Missense Mutation (SNP) | VAF 18/273 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- PACSIN3 | c.950G>A p.G317D | Missense Mutation (SNP) | VAF 148/607 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PAPOLA | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 122/368 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PCDHB12 | c.218A>C p.E73A | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PCOLCE | c.176del p.P59Lfs*9 | Frame Shift Del (DEL) | VAF 11/88 reads (13%) | called by mutect2, pindel, varscan2
- PHF21B | c.1546T>G p.S516A | Missense Mutation (SNP) | VAF 91/295 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIK3R5 | c.1441del p.Q481Sfs*26 | Frame Shift Del (DEL) | VAF 67/271 reads (25%) | called by mutect2, pindel, varscan2
- PIWIL1 | c.1719del p.K573Nfs*19 | Frame Shift Del (DEL) | VAF 105/360 reads (29%) | called by mutect2, pindel, varscan2
- PKD1 | c.3211T>C p.Y1071H | Missense Mutation (SNP) | VAF 140/590 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLCB3 | c.2752del p.R918Afs*95 | Frame Shift Del (DEL) | VAF 81/282 reads (29%) | called by mutect2, pindel, varscan2
- PLD5 | c.991A>G p.S331G (on ENST00000442594; = p.S269G on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/202 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- PLXND1 | c.2022del p.N675Tfs*5 | Frame Shift Del (DEL) | VAF 50/122 reads (41%) | called by mutect2, pindel, varscan2
- PMEL | c.1088C>A p.P363H | Missense Mutation (SNP) | VAF 87/248 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- POLD1 | c.2959del p.X987_splice | Splice Site (DEL) | VAF 51/233 reads (22%) | called by mutect2, pindel, varscan2
- POLR3B | c.2570+2T>C p.X857_splice | Splice Site (SNP) | VAF 145/417 reads (35%) | called by muse, mutect2, varscan2
- POLR3K | c.287dup p.C97Vfs*31 | Frame Shift Ins (INS) | VAF 63/321 reads (20%) | called by mutect2, pindel, varscan2
- PPP1R12B | c.2534C>T p.T845I | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PPP2R3A | c.793G>T p.G265* | Nonsense Mutation (SNP) | VAF 37/161 reads (23%) | called by muse, mutect2, varscan2
- PPP2R3B | c.1165del p.T389Hfs*70 | Frame Shift Del (DEL) | VAF 75/266 reads (28%) | called by mutect2, pindel, varscan2
- PRDM13 | c.1076A>T p.H359L | Missense Mutation (SNP) | VAF 96/222 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- PRDM2 | c.3137C>T p.P1046L | Missense Mutation (SNP) | VAF 8/183 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.84); called by muse, mutect2
- PRPF40B | c.605del p.P202Hfs*86 (on ENST00000380281; = p.P196Hfs*86 on NM_012272.3) | Frame Shift Del (DEL) | VAF 88/220 reads (40%) | called by mutect2, pindel, varscan2
- PSIP1 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PTPRF | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PXDN | c.3569del p.N1190Mfs*12 | Frame Shift Del (DEL) | VAF 30/144 reads (21%) | called by mutect2, pindel
- PYROXD2 | c.607A>G p.K203E | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.028); called by muse, mutect2
- RAB26 | c.247T>A p.F83I | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RABEPK | c.170A>T p.N57I | Missense Mutation (SNP) | VAF 79/235 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- RASGRP4 | c.1670G>A p.C557Y | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RERE | c.3323del p.P1108Lfs*149 | Frame Shift Del (DEL) | VAF 38/183 reads (21%) | called by pindel, varscan2
- RERE | c.2053G>T p.G685* | Nonsense Mutation (SNP) | VAF 176/602 reads (29%) | called by muse, mutect2, varscan2
- RGPD8 | c.4800del p.K1600Nfs*69 | Frame Shift Del (DEL) | VAF 11/55 reads (20%) | called by mutect2, varscan2
- RGS3 | c.2384T>G p.L795R (on ENST00000350696 / NM_001282923.2; = p.L514R on NM_130795.4) | Missense Mutation (SNP) | VAF 48/215 reads (22%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- RIBC1 | c.847G>T p.A283S | Missense Mutation (SNP) | VAF 12/341 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.027); called by muse, mutect2
- RIPOR1 | c.1764_1766del p.T589del (on ENST00000379312 / NM_001193522.2; = p.T585del on NM_024519.4) | In Frame Del (DEL) | VAF 76/330 reads (23%) | called by pindel, varscan2
- RLN2 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 141/482 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- RNF208 | c.241dup p.D81Gfs*20 | Frame Shift Ins (INS) | VAF 14/40 reads (35%) | called by mutect2, varscan2
- RNF225 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- RPN2 | c.229T>G p.S77A | Missense Mutation (SNP) | VAF 103/547 reads (19%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- RTF1 | c.512_513del p.S171Ffs*5 | Frame Shift Del (DEL) | VAF 60/290 reads (21%) | called by pindel, varscan2
- SACS | c.2047G>A p.V683I | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SAFB | c.344A>C p.D115A | Missense Mutation (SNP) | VAF 83/255 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SCAF8 | c.818_819del p.S273* | Frame Shift Del (DEL) | VAF 84/334 reads (25%) | called by pindel, varscan2
- SCN4A | c.1072del p.L358Cfs*46 | Frame Shift Del (DEL) | VAF 71/273 reads (26%) | called by mutect2, pindel, varscan2
- SCN5A | c.5002A>G p.M1668V (on ENST00000333535 / NM_198056.3; = p.M1667V on NM_000335.5) | Missense Mutation (SNP) | VAF 116/468 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- SEC23B | c.1738C>T p.P580S | Missense Mutation (SNP) | VAF 27/211 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SETD1B | c.22del p.H8Tfs*27 | Frame Shift Del (DEL) | VAF 10/77 reads (13%) | called by mutect2, varscan2
- SIDT1 | c.2118del p.R707Gfs*25 | Frame Shift Del (DEL) | VAF 110/353 reads (31%) | called by mutect2, pindel, varscan2
- SIPA1L2 | c.5163del p.K1721Nfs*20 | Frame Shift Del (DEL) | VAF 62/231 reads (27%) | called by mutect2, pindel, varscan2
- SLC10A7 | c.590G>A p.R197K | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- SLC12A2 | c.2203G>A p.A735T | Missense Mutation (SNP) | VAF 71/213 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- SLC25A33 | c.53G>A p.G18D | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- SLC38A10 | c.2471_2472del p.T824Rfs*142 | Frame Shift Del (DEL) | VAF 27/91 reads (30%) | called by pindel, varscan2
- SLC38A5 | c.482A>T p.D161V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.371); called by muse, mutect2
- SLC6A1 | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 161/487 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC6A7 | c.1615G>A p.G539S | Missense Mutation (SNP) | VAF 58/204 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMARCC2 | c.347G>C p.R116P | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SMC1A | c.3520A>G p.I1174V | Missense Mutation (SNP) | VAF 34/610 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- SMC1A | c.1732-6C>A | Splice Region (SNP) | VAF 15/492 reads (3%) | called by muse, mutect2
- SMC4 | c.1692del p.K564Nfs*27 | Frame Shift Del (DEL) | VAF 32/104 reads (31%) | called by mutect2, pindel, varscan2
- SOAT2 | c.1171T>C p.Y391H | Missense Mutation (SNP) | VAF 105/381 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SOGA1 | c.4267C>A p.L1423M | Missense Mutation (SNP) | VAF 76/272 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SORT1 | c.757C>T p.H253Y | Missense Mutation (SNP) | VAF 66/227 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- SOWAHC | c.630G>T p.M210I | Missense Mutation (SNP) | VAF 197/631 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPAG17 | c.1653G>T p.M551I | Missense Mutation (SNP) | VAF 87/268 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SPATA1 | c.658del p.S220Vfs*45 | Frame Shift Del (DEL) | VAF 37/139 reads (27%) | called by mutect2, pindel, varscan2
- SPDEF | c.829+2T>C p.X277_splice | Splice Site (SNP) | VAF 12/168 reads (7%) | called by muse, mutect2
- SPRR2E | c.107G>A p.C36Y | Missense Mutation (SNP) | VAF 79/509 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SRM | c.637C>T p.H213Y | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- STIM2 | c.353A>T p.H118L | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- STRN3 | c.905T>C p.L302P | Missense Mutation (SNP) | VAF 56/235 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SUV39H1 | c.592del p.A198Rfs*140 | Frame Shift Del (DEL) | VAF 87/368 reads (24%) | called by mutect2, pindel, varscan2
- SVEP1 | c.1817A>G p.H606R | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SVIL | c.5524dup p.A1842Gfs*39 (on ENST00000355867 / NM_021738.3; = p.A1416Gfs*39 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 175/700 reads (25%) | called by pindel, varscan2
- SYDE2 | c.251G>A p.S84N | Missense Mutation (SNP) | VAF 86/252 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- SYNE1 | c.24847del p.L8283Wfs*49 (on ENST00000367255 / NM_182961.4; = p.L8212Wfs*45 on NM_033071.3) | Frame Shift Del (DEL) | VAF 51/200 reads (26%) | called by mutect2, pindel, varscan2
- TACC1 | c.1662C>T p.G554= | Splice Region (SNP) | VAF 74/248 reads (30%) | called by muse, mutect2, varscan2
- TAF2 | c.2350_2354dup p.K786Tfs*15 | Frame Shift Ins (INS) | VAF 19/100 reads (19%) | called by pindel, varscan2
- TAX1BP1 | c.131C>A p.P44Q | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBX21 | c.464_467del p.T155Rfs*2 | Frame Shift Del (DEL) | VAF 136/612 reads (22%) | called by pindel, varscan2
- TBX4 | c.1517C>T p.P506L | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- TDRD12 | c.372del p.K124Nfs*41 | Frame Shift Del (DEL) | VAF 87/315 reads (28%) | called by mutect2, pindel, varscan2
- TDRD15 | c.1899del p.D634Mfs*6 | Frame Shift Del (DEL) | VAF 43/145 reads (30%) | called by mutect2, pindel, varscan2
- TESC | c.350-1G>T p.X117_splice | Splice Site (SNP) | VAF 11/325 reads (3%) | called by muse, mutect2
- TESK1 | c.1107del p.N370Tfs*6 | Frame Shift Del (DEL) | VAF 49/202 reads (24%) | called by mutect2, pindel, varscan2
- THAP7 | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 101/336 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- THTPA | c.37C>A p.L13I | Missense Mutation (SNP) | VAF 7/167 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- TMEFF2 | c.895C>T p.H299Y | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.114); called by muse, varscan2
- TMEM132B | c.2444G>A p.S815N | Missense Mutation (SNP) | VAF 111/294 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- TMEM267 | c.214A>G p.K72E | Missense Mutation (SNP) | VAF 77/413 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- TMEM72 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 111/382 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TMPRSS3 | c.1209del p.L405Wfs*11 | Frame Shift Del (DEL) | VAF 92/409 reads (22%) | called by mutect2, pindel, varscan2
- TMPRSS9 | c.2434A>G p.S812G (on ENST00000648592; = p.S778G on NM_182973.2) | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TNFRSF11B | c.253C>A p.P85T | Missense Mutation (SNP) | VAF 106/297 reads (36%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- TOB2 | c.584del p.G195Afs*9 | Frame Shift Del (DEL) | VAF 48/217 reads (22%) | called by mutect2, pindel, varscan2
- TRIM7 | c.1526T>C p.I509T | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, varscan2
- TSPAN15 | c.96+2T>C p.X32_splice | Splice Site (SNP) | VAF 19/56 reads (34%) | called by muse, mutect2, varscan2
- TTN | c.92230A>G p.T30744A (on ENST00000591111; = p.T23320A on NM_003319.4) | Missense Mutation (SNP) | VAF 46/119 reads (39%) | PolyPhen benign (0.194); called by muse, mutect2, varscan2
- TTN | c.63569T>C p.L21190P (on ENST00000591111; = p.L13766P on NM_003319.4) | Missense Mutation (SNP) | VAF 30/159 reads (19%) | PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TULP3 | c.810-2A>G p.X270_splice | Splice Site (SNP) | VAF 18/100 reads (18%) | called by muse, mutect2, varscan2
- TULP4 | c.2011C>A p.P671T | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- UBR5 | c.2230dup p.T744Nfs*29 | Frame Shift Ins (INS) | VAF 59/194 reads (30%) | called by mutect2, pindel, varscan2
- UCP1 | c.115G>A p.V39I | Missense Mutation (SNP) | VAF 54/606 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- UNC5C | c.445T>C p.S149P | Missense Mutation (SNP) | VAF 135/433 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- UNC79 | c.2836T>C p.Y946H (on ENST00000393151 / NM_001346218.2; = p.Y769H on NM_020818.5) | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP17L4 | c.835G>A p.V279I | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by mutect2, varscan2
- UTP20 | c.7841G>A p.G2614D | Missense Mutation (SNP) | VAF 130/414 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- VPS4B | c.1287C>A p.D429E | Missense Mutation (SNP) | VAF 62/214 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VSX2 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 65/223 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- VWA5B1 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- WASHC2A | c.1238del p.L413* | Frame Shift Del (DEL) | VAF 33/237 reads (14%) | called by mutect2, pindel, varscan2
- WDR5 | c.741+1G>A p.X247_splice | Splice Site (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- WDR81 | c.4762del p.V1588Wfs*15 (on ENST00000409644 / NM_001163809.2; = p.V537Wfs*15 on NM_152348.4) | Frame Shift Del (DEL) | VAF 43/226 reads (19%) | called by mutect2, pindel, varscan2
- XKR3 | c.304del p.W102Gfs*6 | Frame Shift Del (DEL) | VAF 20/55 reads (36%) | called by mutect2, pindel, varscan2
- XKR5 | c.1897A>G p.K633E | Missense Mutation (SNP) | VAF 87/333 reads (26%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2, varscan2
- YEATS2 | c.1683G>A p.M561I | Missense Mutation (SNP) | VAF 80/326 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- ZBED6 | c.1541G>A p.G514D | Missense Mutation (SNP) | VAF 24/358 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- ZFHX2 | c.5857G>A p.G1953S | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); called by muse, mutect2
- ZKSCAN4 | c.902G>A p.G301D | Missense Mutation (SNP) | VAF 117/487 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- ZNF335 | c.1141C>T p.Q381* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | called by mutect2, varscan2
- ZNF385B | c.1092T>G p.H364Q | Missense Mutation (SNP) | VAF 62/185 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF417 | c.821G>T p.G274V | Missense Mutation (SNP) | VAF 66/569 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- ZNF44 | c.1426A>G p.K476E (on ENST00000356109 / NM_001164276.2; = p.K428E on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF473 | c.493G>A p.G165R | Missense Mutation (SNP) | VAF 85/275 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ZNF628 | c.832G>A p.V278M | Missense Mutation (SNP) | VAF 128/369 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- ZNF667 | c.628A>G p.N210D | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ZXDA | c.376dup p.D126Gfs*52 | Frame Shift Ins (INS) | VAF 84/279 reads (30%) | called by mutect2, pindel, varscan2
- ABCA2 | c.1248C>T p.G416= (on ENST00000614293; = p.G386= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 51/174 reads (29%) | catalogued as rs770999419, COSV99688684; called by muse, mutect2, varscan2
- ACR | c.522C>A p.S174= | Silent (SNP) | VAF 79/296 reads (27%) | called by muse, mutect2, varscan2
- ACSM6 | c.879C>T p.H293= | Silent (SNP) | VAF 94/363 reads (26%) | catalogued as rs775473572; called by muse, mutect2, varscan2
- ACTR8 | c.195C>T p.D65= | Silent (SNP) | VAF 18/246 reads (7%) | called by muse, mutect2
- ADCY6 | c.309G>A p.T103= | Silent (SNP) | VAF 56/176 reads (32%) | catalogued as rs781587179; called by muse, mutect2, varscan2
- ADD2 | c.114G>A p.A38= | Silent (SNP) | VAF 101/385 reads (26%) | catalogued as rs1553374413, COSV52466809; called by muse, mutect2, varscan2
- ADGRA1 | c.726C>T p.G242= | Silent (SNP) | VAF 48/206 reads (23%) | catalogued as rs755111182; called by muse, mutect2, varscan2
- ADRB1 | c.672C>T p.Y224= | Silent (SNP) | VAF 116/492 reads (24%) | catalogued as rs776386195; called by muse, mutect2, varscan2
- AIDA | c.804T>C p.P268= | Silent (SNP) | VAF 46/185 reads (25%) | called by muse, mutect2, varscan2
- AIFM1 | c.1350G>A p.R450= | Silent (SNP) | VAF 33/470 reads (7%) | called by muse, mutect2
- AKAP12 | c.4221C>T p.C1407= | Silent (SNP) | VAF 72/217 reads (33%) | called by muse, mutect2, varscan2
- APC2 | c.6153G>A p.R2051= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs1480749288; called by muse, mutect2, varscan2
- APOBEC3F | c.1104G>A p.L368= | Silent (SNP) | VAF 46/124 reads (37%) | catalogued as rs1422445885; called by muse, mutect2, varscan2
- ARHGAP10 | c.2106G>A p.V702= | Silent (SNP) | VAF 133/440 reads (30%) | catalogued as rs1205538755; called by muse, mutect2, varscan2
- ATP1A3 | c.552C>T p.N184= (on ENST00000545399 / NM_001256214.2; = p.N171= on NM_152296.5) | Silent (SNP) | VAF 43/671 reads (6%) | catalogued as rs782560151, COSV57485117; called by muse, mutect2
- ATP4A | c.963C>A p.A321= | Silent (SNP) | VAF 145/472 reads (31%) | called by muse, mutect2, varscan2
- ATP9B | c.3400A>C p.R1134= | Silent (SNP) | VAF 24/454 reads (5%) | called by muse, mutect2
- BAHCC1 | c.2340C>G p.R780= | Silent (SNP) | VAF 99/368 reads (27%) | called by muse, mutect2, varscan2
- BRD9 | c.1000C>T p.L334= | Silent (SNP) | VAF 104/423 reads (25%) | catalogued as rs1217090942; called by muse, mutect2, varscan2
- C2CD4A | c.277C>T p.L93= | Silent (SNP) | VAF 13/389 reads (3%) | called by muse, mutect2
- CACNA1H | c.2682G>A p.L894= | Silent (SNP) | VAF 36/560 reads (6%) | called by muse, mutect2
- CBL | c.762G>A p.L254= | Silent (SNP) | VAF 31/518 reads (6%) | called by muse, mutect2
- CCDC173 | c.1554C>T p.S518= | Silent (SNP) | VAF 115/378 reads (30%) | called by muse, mutect2, varscan2
- CDK15 | c.219A>G p.P73= (on ENST00000652192 / NM_001366386.2; = p.P22= on NM_139158.2) | Silent (SNP) | VAF 89/348 reads (26%) | called by muse, mutect2, varscan2
- CDK3 | c.483T>C p.H161= | Silent (SNP) | VAF 70/229 reads (31%) | catalogued as rs1288050052; called by muse, mutect2, varscan2
- CELSR2 | c.3660G>A p.S1220= | Silent (SNP) | VAF 102/305 reads (33%) | called by muse, mutect2, varscan2
- CHST14 | c.753C>T p.P251= | Silent (SNP) | VAF 67/802 reads (8%) | called by muse, mutect2
- CILP2 | c.1851G>A p.S617= | Silent (SNP) | VAF 10/221 reads (5%) | catalogued as COSV99365168; called by muse, mutect2
- CMTR2 | c.1788G>A p.P596= | Silent (SNP) | VAF 38/107 reads (36%) | catalogued as rs543435476; called by muse, mutect2, varscan2
- COL5A1 | c.2526T>C p.P842= | Silent (SNP) | VAF 70/223 reads (31%) | catalogued as rs763634004; ClinVar: likely benign; called by muse, mutect2, varscan2
- CP | c.900C>T p.H300= | Silent (SNP) | VAF 44/367 reads (12%) | catalogued as rs757188910, COSV52833177; called by muse, mutect2, varscan2
- CPNE3 | c.651T>C p.Y217= | Silent (SNP) | VAF 43/146 reads (29%) | called by muse, mutect2, varscan2
- CYTH3 | c.678C>T p.N226= | Silent (SNP) | VAF 10/236 reads (4%) | catalogued as rs1430762569; called by muse, mutect2
- DCAKD | c.525C>A p.V175= | Silent (SNP) | VAF 49/166 reads (30%) | called by muse, mutect2, varscan2
- DCHS2 | c.159C>T p.H53= | Silent (SNP) | VAF 16/350 reads (5%) | catalogued as rs1459633637; called by muse, mutect2
- DGKH | c.1350T>C p.S450= | Silent (SNP) | VAF 64/183 reads (35%) | called by muse, mutect2, varscan2
- DLG1 | c.681T>C p.L227= | Silent (SNP) | VAF 38/135 reads (28%) | called by muse, mutect2, varscan2
- DOCK4 | c.3828C>T p.C1276= | Silent (SNP) | VAF 57/192 reads (30%) | called by muse, mutect2, varscan2
- DTWD1 | c.12T>C p.N4= | Silent (SNP) | VAF 31/103 reads (30%) | called by muse, varscan2
- FARP2 | c.1557C>T p.A519= | Silent (SNP) | VAF 35/108 reads (32%) | catalogued as rs746457263; called by muse, mutect2, varscan2
- FBLN2 | c.2088T>C p.V696= | Silent (SNP) | VAF 27/448 reads (6%) | called by muse, mutect2
- FGD3 | c.2052C>T p.S684= | Silent (SNP) | VAF 91/389 reads (23%) | catalogued as rs373857408, COSV100490521; called by muse, mutect2, varscan2
- FXR1 | c.891T>A p.I297= | Silent (SNP) | VAF 39/92 reads (42%) | catalogued as COSV59761197; called by muse, mutect2, varscan2
- GAD2 | c.1272C>T p.S424= | Silent (SNP) | VAF 75/301 reads (25%) | called by muse, mutect2, varscan2
- GNA12 | c.1068C>T p.T356= | Silent (SNP) | VAF 50/205 reads (24%) | catalogued as rs748435612; called by muse, mutect2, varscan2
- GPATCH2L | c.576T>A p.T192= | Silent (SNP) | VAF 22/354 reads (6%) | called by muse, mutect2
- GPT | c.678C>T p.G226= | Silent (SNP) | VAF 93/285 reads (33%) | called by muse, mutect2, varscan2
- GREM2 | c.249C>T p.S83= | Silent (SNP) | VAF 33/366 reads (9%) | catalogued as COSV58950057; called by muse, mutect2
- GRIA2 | c.138A>G p.V46= | Silent (SNP) | VAF 63/171 reads (37%) | called by muse, mutect2, varscan2
- HCAR2 | c.741C>T p.S247= | Silent (SNP) | VAF 155/719 reads (22%) | catalogued as rs201091527, COSV61025704; called by muse, mutect2, varscan2
- HOOK2 | c.1989C>T p.L663= | Silent (SNP) | VAF 89/294 reads (30%) | called by muse, mutect2, varscan2
- HTRA1 | c.375C>A p.T125= | Silent (SNP) | VAF 204/708 reads (29%) | catalogued as rs12244085; called by muse, mutect2, varscan2
- IL12B | c.117G>A p.P39= | Silent (SNP) | VAF 36/536 reads (7%) | catalogued as COSV51456137; called by muse, mutect2
- IL6 | c.405T>C p.S135= | Silent (SNP) | VAF 69/298 reads (23%) | called by muse, mutect2, varscan2
- INSYN2A | c.1299G>T p.P433= | Silent (SNP) | VAF 41/181 reads (23%) | called by muse, mutect2, varscan2
- IRF7 | c.150C>T p.R50= (on ENST00000397566; = p.R37= on NM_001572.5) | Silent (SNP) | VAF 26/446 reads (6%) | called by muse, mutect2
- KANK4 | c.909C>T p.I303= | Silent (SNP) | VAF 16/238 reads (7%) | catalogued as rs770579598, COSV100587091; called by muse, mutect2
- KAT2A | c.438G>A p.L146= | Silent (SNP) | VAF 50/388 reads (13%) | called by muse, mutect2, varscan2
- KCNH2 | c.3366G>C p.P1122= | Silent (SNP) | VAF 26/303 reads (9%) | catalogued as COSV51235326; called by muse, mutect2
- KCNH6 | c.774G>A p.V258= | Silent (SNP) | VAF 150/544 reads (28%) | catalogued as rs201741011; called by muse, mutect2, varscan2
- KIF21B | c.3990C>T p.C1330= (on ENST00000422435 / NM_001252100.2; = p.C1317= on NM_017596.4) | Silent (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- LDLR | c.1305G>A p.E435= | Silent (SNP) | VAF 54/760 reads (7%) | called by muse, mutect2
- LRR1 | c.366G>A p.T122= | Silent (SNP) | VAF 28/89 reads (31%) | catalogued as rs751540511; called by muse, mutect2
- LTBP2 | c.2415T>C p.P805= | Silent (SNP) | VAF 37/607 reads (6%) | called by muse, mutect2
- MACF1 | c.5031G>A p.L1677= | Silent (SNP) | VAF 11/164 reads (7%) | called by muse, mutect2
- MACF1 | c.18771A>G p.E6257= (on ENST00000372915; = p.E4302= on NM_012090.5) | Silent (SNP) | VAF 43/168 reads (26%) | called by muse, mutect2, varscan2
- MAGI1 | c.468C>T p.G156= | Silent (SNP) | VAF 98/339 reads (29%) | catalogued as rs778906272, COSV58322638; called by muse, mutect2, varscan2
- MATN4 | c.558G>A p.S186= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as COSV59215613; called by muse, mutect2, varscan2
- MKKS | c.1176G>A p.T392= | Silent (SNP) | VAF 114/364 reads (31%) | catalogued as rs1441106610, COSV61400022; called by muse, mutect2, varscan2
- MMP14 | c.951C>T p.N317= | Silent (SNP) | VAF 57/265 reads (22%) | called by muse, mutect2, varscan2
- MMRN2 | c.1623C>T p.D541= | Silent (SNP) | VAF 74/199 reads (37%) | catalogued as rs1179516493; called by muse, mutect2, varscan2
- MRPL37 | c.459C>T p.C153= | Silent (SNP) | VAF 58/199 reads (29%) | catalogued as rs370161335; called by muse, mutect2, varscan2
- MTR | c.1707T>C p.P569= | Silent (SNP) | VAF 64/366 reads (17%) | catalogued as rs760490684, COSV63965491; called by muse, mutect2, varscan2
- NEK9 | c.18G>A p.E6= | Silent (SNP) | VAF 35/100 reads (35%) | called by muse, mutect2, varscan2
- NEUROD6 | c.861C>T p.Y287= | Silent (SNP) | VAF 114/378 reads (30%) | catalogued as rs1223833286, COSV51769388; called by muse, mutect2, varscan2
- NSD1 | c.3939A>G p.E1313= | Silent (SNP) | VAF 10/319 reads (3%) | called by muse, mutect2
- NUGGC | c.957C>T p.S319= | Silent (SNP) | VAF 50/166 reads (30%) | catalogued as rs1281870278; called by muse, mutect2, varscan2
- OBSCN | c.19302T>C p.T6434= | Silent (SNP) | VAF 16/218 reads (7%) | called by muse, mutect2
- OGFR | c.657G>A p.S219= | Silent (SNP) | VAF 9/101 reads (9%) | catalogued as rs781191511; called by muse, mutect2
- P2RX1 | c.675C>A p.P225= | Silent (SNP) | VAF 200/810 reads (25%) | catalogued as rs200190306, COSV56653699; called by muse, mutect2, varscan2
- PAPPA | c.3045G>A p.T1015= | Silent (SNP) | VAF 74/269 reads (28%) | catalogued as rs200371548; called by muse, mutect2, varscan2
- PARP10 | c.2856C>T p.D952= | Silent (SNP) | VAF 31/619 reads (5%) | called by muse, mutect2
- PCDHA11 | c.1338C>T p.D446= | Silent (SNP) | VAF 48/614 reads (8%) | catalogued as COSV56476032; called by muse, mutect2
- PCDHA5 | c.564G>A p.T188= | Silent (SNP) | VAF 53/174 reads (30%) | catalogued as rs1347495985, COSV65350902; called by muse, mutect2, varscan2
- PCDHB3 | c.1866C>T p.G622= | Silent (SNP) | VAF 343/1051 reads (33%) | catalogued as COSV50601793; called by muse, mutect2, varscan2
- PCNX3 | c.5749C>A p.R1917= | Silent (SNP) | VAF 35/76 reads (46%) | called by muse, mutect2, varscan2
- PDE7A | c.1425A>G p.L475= (on ENST00000401827 / NM_001242318.3; = p.L449= on NM_002603.4) | Silent (SNP) | VAF 38/276 reads (14%) | called by muse, mutect2, varscan2
- PIK3CD | c.1185C>T p.Y395= | Silent (SNP) | VAF 219/825 reads (27%) | catalogued as rs769070246, COSV100740536; called by muse, mutect2, varscan2
- PLEKHG4B | c.2760G>A p.Q920= (on ENST00000283426; = p.Q1276= on NM_052909.5) | Silent (SNP) | VAF 14/139 reads (10%) | catalogued as rs1363368636; called by muse, mutect2, varscan2
- PMPCA | c.27G>T p.T9= | Silent (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- PORCN | c.306C>T p.T102= | Silent (SNP) | VAF 163/548 reads (30%) | catalogued as COSV58226846; called by muse, mutect2, varscan2
- POSTN | c.1467C>T p.R489= | Silent (SNP) | VAF 96/317 reads (30%) | catalogued as rs1234284132, COSV65711689; called by muse, mutect2, varscan2
- POU5F2 | c.828G>A p.E276= | Silent (SNP) | VAF 27/318 reads (8%) | catalogued as COSV67933591; called by muse, mutect2
- PPAN-P2RY11 | c.2229C>T p.A743= | Silent (SNP) | VAF 81/251 reads (32%) | catalogued as rs3810160, COSV99461474; called by muse, mutect2, varscan2
- PRDM12 | c.717C>G p.P239= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as rs755462565; called by muse, varscan2
- PRF1 | c.1107G>A p.T369= | Silent (SNP) | VAF 135/527 reads (26%) | catalogued as rs145589960; called by muse, mutect2, varscan2
- PRR23A | c.156G>A p.P52= | Silent (SNP) | VAF 68/173 reads (39%) | catalogued as rs1485841888; called by muse, mutect2, varscan2
- PRSS48 | c.345C>T p.V115= | Silent (SNP) | VAF 100/617 reads (16%) | catalogued as rs760837216; called by muse, mutect2, varscan2
- PTCRA | c.456C>T p.V152= | Silent (SNP) | VAF 158/464 reads (34%) | called by muse, varscan2
- PTN | c.189G>T p.G63= | Silent (SNP) | VAF 54/192 reads (28%) | called by muse, mutect2, varscan2
- R3HCC1 | c.549G>A p.L183= (on ENST00000411463; = p.L143= on NM_001136108.3) | Silent (SNP) | VAF 96/372 reads (26%) | called by muse, mutect2
- RAB3GAP1 | c.370C>T p.L124= | Silent (SNP) | VAF 140/477 reads (29%) | called by muse, mutect2, varscan2
- RAD51 | c.459T>C p.G153= | Silent (SNP) | VAF 34/626 reads (5%) | called by muse, mutect2
- RASAL2 | c.3204T>C p.H1068= | Silent (SNP) | VAF 98/318 reads (31%) | called by muse, varscan2
- RBFOX1 | c.825C>T p.R275= | Silent (SNP) | VAF 76/211 reads (36%) | catalogued as rs776943189, COSV60966303; called by muse, varscan2
- RENBP | c.276C>T p.D92= | Silent (SNP) | VAF 86/319 reads (27%) | catalogued as rs371899082; called by muse, mutect2, varscan2
- RGS2 | c.150A>G p.Q50= | Silent (SNP) | VAF 114/502 reads (23%) | catalogued as rs1017458908, COSV52458828; called by muse, mutect2, varscan2
- RHBDL3 | c.1198C>T p.L400= | Silent (SNP) | VAF 142/440 reads (32%) | called by muse, mutect2, varscan2
- S1PR5 | c.909C>A p.P303= | Silent (SNP) | VAF 112/414 reads (27%) | catalogued as rs1170319239, COSV61013363; called by muse, mutect2, varscan2
- SAV1 | c.177C>A p.A59= | Silent (SNP) | VAF 16/164 reads (10%) | called by muse, mutect2
- SCRN2 | c.1182A>G p.T394= | Silent (SNP) | VAF 114/351 reads (32%) | called by muse, mutect2, varscan2
- SIGLEC15 | c.207G>A p.P69= | Silent (SNP) | VAF 46/525 reads (9%) | called by muse, mutect2
- SLC22A7 | c.300C>T p.S100= | Silent (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- SLC26A6 | c.2019G>A p.L673= | Silent (SNP) | VAF 87/265 reads (33%) | called by muse, mutect2, varscan2
- SOGA3 | c.2298G>A p.S766= | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as rs753901509; called by muse, mutect2, varscan2
- SORCS1 | c.183G>A p.R61= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as rs1273209599; called by muse, mutect2, varscan2
- SOX12 | c.543C>A p.T181= | Silent (SNP) | VAF 13/32 reads (41%) | called by mutect2, varscan2
- SPG11 | c.6684C>T p.C2228= | Silent (SNP) | VAF 21/530 reads (4%) | catalogued as COSV99969734; called by muse, mutect2
- SRCIN1 | c.894C>T p.Y298= (on ENST00000621492; = p.Y264= on NM_025248.3) | Silent (SNP) | VAF 94/270 reads (35%) | called by muse, mutect2, varscan2
- TBX15 | c.843G>A p.T281= (on ENST00000369429 / NM_001330677.2; = p.T175= on NM_152380.3) | Silent (SNP) | VAF 114/377 reads (30%) | catalogued as rs1314050363, COSV99254247; called by muse, mutect2, varscan2
- TDRD12 | c.1509G>A p.K503= | Silent (SNP) | VAF 30/94 reads (32%) | called by muse, mutect2, varscan2
- THAP4 | c.1297C>T p.L433= | Silent (SNP) | VAF 38/176 reads (22%) | called by muse, mutect2, varscan2
- TLX2 | c.327C>T p.G109= | Silent (SNP) | VAF 138/468 reads (29%) | called by muse, mutect2, varscan2
- TMEM247 | c.255C>T p.D85= | Silent (SNP) | VAF 117/413 reads (28%) | catalogued as rs1020050838; called by muse, mutect2, varscan2
- TPH2 | c.1026G>A p.A342= | Silent (SNP) | VAF 30/466 reads (6%) | catalogued as rs564050214, COSV61593393; called by muse, mutect2
- TRPV5 | c.639C>T p.C213= | Silent (SNP) | VAF 14/426 reads (3%) | catalogued as COSV54689496; called by muse, mutect2
- TSHZ1 | c.798C>T p.N266= (on ENST00000580243 / NM_001308210.2; = p.N221= on NM_005786.6) | Silent (SNP) | VAF 17/262 reads (6%) | catalogued as rs555310542, COSV59009033; called by muse, mutect2
- TSHZ2 | c.90G>A p.E30= | Silent (SNP) | VAF 34/114 reads (30%) | catalogued as COSV61588654; called by mutect2, varscan2
- TTC37 | c.87T>C p.C29= | Silent (SNP) | VAF 96/310 reads (31%) | called by muse, mutect2, varscan2
- TTLL5 | c.105C>T p.G35= | Silent (SNP) | VAF 31/116 reads (27%) | catalogued as rs762286715; called by muse, mutect2, varscan2
- TUBA4A | c.327C>A p.T109= | Silent (SNP) | VAF 44/136 reads (32%) | called by muse, mutect2, varscan2
- USP11 | c.1239T>C p.H413= (on ENST00000218348; = p.H370= on NM_001371072.1) | Silent (SNP) | VAF 20/91 reads (22%) | called by muse, mutect2, varscan2
- VPS50 | c.28C>A p.R10= | Silent (SNP) | VAF 63/209 reads (30%) | called by muse, mutect2, varscan2
- VWCE | c.2154C>T p.S718= | Silent (SNP) | VAF 23/431 reads (5%) | catalogued as rs749683266; called by muse, mutect2
- VWDE | c.1107C>A p.T369= | Silent (SNP) | VAF 30/408 reads (7%) | called by muse, mutect2
- WASHC5 | c.984C>T p.S328= | Silent (SNP) | VAF 95/431 reads (22%) | called by muse, mutect2, varscan2
- WDR1 | c.702C>T p.D234= (on ENST00000382452; = p.D94= on NM_005112.5) | Silent (SNP) | VAF 36/498 reads (7%) | catalogued as rs576932170; called by muse, mutect2
- WT1 | c.828C>T p.H276= | Silent (SNP) | VAF 52/156 reads (33%) | called by muse, mutect2, varscan2
- ZDHHC13 | c.543T>C p.N181= | Silent (SNP) | VAF 7/142 reads (5%) | called by muse, mutect2
- ZFYVE28 | c.456C>A p.T152= | Silent (SNP) | VAF 28/475 reads (6%) | called by muse, mutect2
- ZMYM6 | c.1155A>T p.A385= | Silent (SNP) | VAF 25/142 reads (18%) | called by muse, mutect2, varscan2
- ZNF230 | c.822T>C p.H274= | Silent (SNP) | VAF 13/257 reads (5%) | called by muse, mutect2
- ZNF717 | c.2232C>T p.V744= | Silent (SNP) | VAF 55/201 reads (27%) | called by muse, varscan2
- ZNF853 | c.1368C>T p.A456= | Silent (SNP) | VAF 46/179 reads (26%) | catalogued as rs894423218; called by muse, mutect2, varscan2
- AC040977.2 | chr17:6985451 G>A | 3'Flank (SNP) | VAF 26/337 reads (8%) | called by muse, mutect2
- AC243919.1 | n.58A>G | RNA (SNP) | VAF 60/265 reads (23%) | called by muse, mutect2, varscan2
- AL136982.4 | n.1394A>T | RNA (SNP) | VAF 272/1059 reads (26%) | called by mutect2, varscan2
- ARHGEF25 | chr12:57621399 G>A | 3'Flank (SNP) | VAF 60/204 reads (29%) | catalogued as rs371909798, COSV54089154; called by muse, mutect2, varscan2
- ARMCX4 | c.1038+2672A>G | Intron (SNP) | VAF 40/162 reads (25%) | called by muse, mutect2, varscan2
- ASIC2 | c.556-179790G>A | Intron (SNP) | VAF 81/270 reads (30%) | catalogued as rs1385734473; called by muse, varscan2
- BOD1P2 | n.166G>A | RNA (SNP) | VAF 10/127 reads (8%) | called by muse, mutect2
- C10orf143 | c.69+2351G>A | Intron (SNP) | VAF 21/288 reads (7%) | catalogued as rs1564973911; called by muse, mutect2
- C12orf4 | c.1238-2082dup | Intron (INS) | VAF 48/190 reads (25%) | catalogued as rs1382722088; called by mutect2, pindel, varscan2
- C19orf12 | chr19:29715431 C>T | 5'Flank (SNP) | VAF 32/122 reads (26%) | catalogued as rs1451640309; called by muse, mutect2, varscan2
- CACNA2D1 | c.1931-701del | Intron (DEL) | VAF 106/404 reads (26%) | called by pindel, varscan2
- CASP9 | chr1:15524240 C>T | 5'Flank (SNP) | VAF 77/351 reads (22%) | called by muse, mutect2, varscan2
- CDKL1 | c.172-3882C>T | Intron (SNP) | VAF 18/63 reads (29%) | catalogued as rs1310155681; called by muse, mutect2, varscan2
- CFAP44 | c.*4490C>A | 3'UTR (SNP) | VAF 60/203 reads (30%) | called by muse, mutect2, varscan2
- CHD3 | chr17:7885004 del C | 5'Flank (DEL) | VAF 10/39 reads (26%) | called by mutect2, pindel, varscan2
- COL20A1 | c.3295-71T>C | Intron (SNP) | VAF 12/196 reads (6%) | called by muse, mutect2
- DCAF17 | c.*188del | 3'UTR (DEL) | VAF 86/236 reads (36%) | catalogued as rs746203651; called by mutect2, varscan2
- DCHS2 | n.8343C>A | RNA (SNP) | VAF 30/96 reads (31%) | catalogued as COSV61779694; called by muse, mutect2, varscan2
- DOK1 | c.-12C>A | 5'UTR (SNP) | VAF 77/203 reads (38%) | called by muse, mutect2, varscan2
- DOK3 | chr5:177503300 C>T | 3'Flank (SNP) | VAF 129/397 reads (32%) | called by muse, mutect2, varscan2
- EIF2B5 | c.867+83del | Intron (DEL) | VAF 114/369 reads (31%) | called by mutect2, pindel, varscan2
- ELOB | c.*460G>A | 3'UTR (SNP) | VAF 22/441 reads (5%) | called by muse, mutect2
- FADS1 | chr11:61821386 del A | 5'Flank (DEL) | VAF 48/154 reads (31%) | called by mutect2, varscan2
- FRMD8P1 | n.660C>T | RNA (SNP) | VAF 138/476 reads (29%) | called by muse, mutect2, varscan2
- GATB | c.328-2681del | Intron (DEL) | VAF 21/106 reads (20%) | catalogued as rs755480310; called by mutect2, varscan2
- GLYATL1 | n.111del | RNA (DEL) | VAF 95/454 reads (21%) | catalogued as rs1031672723; called by mutect2, pindel, varscan2
- GLYCTK | c.*313C>T | 3'UTR (SNP) | VAF 36/706 reads (5%) | catalogued as rs975285744; called by muse, mutect2
- GVINP1 | n.6556del | RNA (DEL) | VAF 14/62 reads (23%) | called by mutect2, pindel, varscan2
- HERC2P2 | n.1933C>T | RNA (SNP) | VAF 6/47 reads (13%) | called by mutect2, varscan2
- HERC2P3 | n.313C>T | RNA (SNP) | VAF 12/28 reads (43%) | called by mutect2, varscan2
- HNRNPA2B1 | c.7-9del | Intron (DEL) | VAF 30/99 reads (30%) | catalogued as rs57800062, COSV61159208; called by mutect2, varscan2
- IGF2BP2 | c.240-18275A>G | Intron (SNP) | VAF 110/463 reads (24%) | catalogued as rs767691129; called by muse, mutect2, varscan2
- IGHV1-3 | c.-12C>T | 5'UTR (SNP) | VAF 15/361 reads (4%) | called by muse, mutect2
- INF2 | c.*1+562del | Intron (DEL) | VAF 105/468 reads (22%) | catalogued as rs940215729; called by mutect2, pindel, varscan2
- ISCU | c.115-95C>T | Intron (SNP) | VAF 107/448 reads (24%) | catalogued as rs771921502; called by muse, mutect2, varscan2
- ITGA4 | c.*2220del | 3'UTR (DEL) | VAF 11/24 reads (46%) | catalogued as rs748981170; called by mutect2, varscan2
- JPH3 | c.2167-1165G>A | Intron (SNP) | VAF 82/371 reads (22%) | catalogued as rs566573320; called by muse, mutect2, varscan2
- KAT6B | c.*31G>T | 3'UTR (SNP) | VAF 141/465 reads (30%) | catalogued as rs1415303618; called by muse, mutect2, varscan2
- KCTD1 | c.-15-46257A>G | Intron (SNP) | VAF 80/272 reads (29%) | called by muse, mutect2, varscan2
- KCTD13 | c.*303del | 3'UTR (DEL) | VAF 57/212 reads (27%) | called by mutect2, pindel, varscan2
- KDM2B | c.1048-3059A>T | Intron (SNP) | VAF 71/214 reads (33%) | called by muse, mutect2, varscan2
- KDM6A | c.1528-6del | Intron (DEL) | VAF 104/382 reads (27%) | called by mutect2, pindel, varscan2
- KLF6 | c.*1975C>T | 3'UTR (SNP) | VAF 113/383 reads (30%) | catalogued as rs1309891379; called by muse, mutect2, varscan2
- LAMA1 | c.7051-9T>G | Intron (SNP) | VAF 116/415 reads (28%) | called by muse, mutect2, varscan2
- LIMA1 | c.166-59A>G | Intron (SNP) | VAF 79/230 reads (34%) | called by muse, mutect2, varscan2
- LRP5L | n.703G>A | RNA (SNP) | VAF 153/452 reads (34%) | called by muse, mutect2, varscan2
- MAGEA4 | c.-121C>T | 5'UTR (SNP) | VAF 10/297 reads (3%) | catalogued as COSV99367560; called by muse, mutect2
- MAP4K4 | chr2:101698057 ins T | 5'Flank (INS) | VAF 43/167 reads (26%) | called by mutect2, pindel, varscan2
- MCF2L2 | c.77-10573del | Intron (DEL) | VAF 33/111 reads (30%) | catalogued as rs34320996; called by mutect2, pindel, varscan2
- MCRIP2 | c.-2T>G | 5'UTR (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- MIR6859-3 | chr15:101977682 C>T | 3'Flank (SNP) | VAF 33/295 reads (11%) | called by muse, mutect2, varscan2
- MLIP | c.613-11595del | Intron (DEL) | VAF 93/327 reads (28%) | called by mutect2, pindel, varscan2
- MORF4L1 | c.41-1657del | Intron (DEL) | VAF 70/219 reads (32%) | called by mutect2, varscan2
- MST1L | n.382C>A | RNA (SNP) | VAF 42/821 reads (5%) | catalogued as rs1393132302; called by muse, mutect2
- MYRF | c.46+4414C>T | Intron (SNP) | VAF 79/307 reads (26%) | catalogued as rs1229407544, COSV99606966; called by muse, mutect2, varscan2
- NAGPA | c.921-218del | Intron (DEL) | VAF 109/308 reads (35%) | catalogued as rs746682627; called by mutect2, varscan2
- NLN | c.1527+20del | Intron (DEL) | VAF 98/578 reads (17%) | catalogued as rs751912094, COSV66765184; called by pindel, varscan2
- NLRX1 | c.*219G>A | 3'UTR (SNP) | VAF 95/300 reads (32%) | called by muse, mutect2, varscan2
- NRXN1 | c.3365-109951C>A | Intron (SNP) | VAF 28/71 reads (39%) | called by muse, varscan2
- OLFM1 | c.-32C>T | 5'UTR (SNP) | VAF 12/208 reads (6%) | called by muse, mutect2
- OPLAH | c.2512-20C>A | Intron (SNP) | VAF 189/552 reads (34%) | catalogued as rs782368652; called by muse, mutect2, varscan2
- PAX1 | c.287-32del | Intron (DEL) | VAF 96/351 reads (27%) | catalogued as rs770495252, COSV101270392; called by mutect2, pindel, varscan2
- PGAP6 | chr16:386720 del AAAAACC | 5'Flank (DEL) | VAF 7/65 reads (11%) | called by pindel, varscan2*
- PIK3CD | c.-138+2194A>G | Intron (SNP) | VAF 32/377 reads (8%) | catalogued as rs1229511051; called by muse, mutect2
- POLE | c.5378+608C>T | Intron (SNP) | VAF 16/243 reads (7%) | called by muse, mutect2
- POU2F2 | c.303+456del | Intron (DEL) | VAF 11/43 reads (26%) | catalogued as rs755403965; called by mutect2, varscan2
- PSME3 | c.42+130G>A | Intron (SNP) | VAF 38/156 reads (24%) | catalogued as rs1232751032; called by muse, mutect2, varscan2
- RPL28 | c.325-74del | Intron (DEL) | VAF 8/51 reads (16%) | called by mutect2, pindel, varscan2
- SECISBP2 | c.801+40C>A | Intron (SNP) | VAF 11/109 reads (10%) | called by muse, mutect2
- SFT2D1 | c.351+18T>C | Intron (SNP) | VAF 12/158 reads (8%) | catalogued as rs565749077; called by muse, mutect2
- SIL1 | c.767+19G>A | Intron (SNP) | VAF 173/541 reads (32%) | catalogued as rs551887742; called by muse, mutect2, varscan2
- SLC38A6 | c.1291-14dup | Intron (INS) | VAF 54/153 reads (35%) | catalogued as rs774089549; called by mutect2, pindel, varscan2
- SLC45A4 | c.*77G>A | 3'UTR (SNP) | VAF 16/196 reads (8%) | catalogued as rs144361805, COSV50133610; called by muse, mutect2
- SNAP23 | c.100-189G>A | Intron (SNP) | VAF 8/154 reads (5%) | called by muse, mutect2
- SNX20 | chr16:50669138 G>T | 3'Flank (SNP) | VAF 60/192 reads (31%) | catalogued as rs763244920; called by muse, mutect2, varscan2
- SPRYD4 | c.*8695A>C | 3'UTR (SNP) | VAF 20/226 reads (9%) | called by muse, mutect2
- SPTB | c.6023-25del | Intron (DEL) | VAF 102/424 reads (24%) | catalogued as rs1224414563; called by mutect2, pindel, varscan2
- SSPOP | n.8581del | RNA (DEL) | VAF 98/314 reads (31%) | catalogued as rs552397911; called by mutect2, varscan2
- STX1B | c.*9del | 3'UTR (DEL) | VAF 16/110 reads (15%) | catalogued as rs750392809; called by mutect2, varscan2
- SYTL2 | c.1459+507G>T | Intron (SNP) | VAF 65/271 reads (24%) | called by muse, mutect2, varscan2
- TBX1 | c.1009+581C>A | Intron (SNP) | VAF 72/191 reads (38%) | called by muse, mutect2, varscan2
- TCN1 | c.*43G>A | 3'UTR (SNP) | VAF 85/265 reads (32%) | called by muse, mutect2, varscan2
- TGIF1 | c.*17A>G | 3'UTR (SNP) | VAF 77/362 reads (21%) | called by muse, mutect2, varscan2
- TMEM218 | c.-76T>C | 5'UTR (SNP) | VAF 83/290 reads (29%) | called by muse, mutect2, varscan2
- TMEM255A | c.424-214A>G | Intron (SNP) | VAF 39/174 reads (22%) | called by muse, mutect2, varscan2
- TMEM33 | c.-5C>A | 5'UTR (SNP) | VAF 20/574 reads (3%) | called by muse, mutect2
- TNFRSF10B | c.*2196A>T | 3'UTR (SNP) | VAF 47/112 reads (42%) | called by muse, mutect2, varscan2
- TOGARAM1 | c.4154+1759T>C | Intron (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- TWF1 | c.103+248G>A | Intron (SNP) | VAF 20/72 reads (28%) | called by muse, mutect2, varscan2
- UBBP4 | n.819C>T | RNA (SNP) | VAF 268/815 reads (33%) | catalogued as rs1263204203; called by muse, varscan2
- UFSP2 | c.*422G>T | 3'UTR (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- VIM | c.721-14T>A | Intron (SNP) | VAF 34/654 reads (5%) | called by muse, mutect2
- VPS29 | c.3+398C>T | Intron (SNP) | VAF 159/532 reads (30%) | called by muse, mutect2, varscan2
- VRK3 | chr19:49971877 G>C | 3'Flank (SNP) | VAF 33/115 reads (29%) | catalogued as rs537188216; called by muse, varscan2
- VRK3 | chr19:49973101 G>A | 3'Flank (SNP) | VAF 62/222 reads (28%) | catalogued as rs893998609; called by muse, mutect2, varscan2
